Somatic mutation profile of tumor specimen MP2PRT-PAPUSM-TMP1-A (aliquot MP2PRT-PAPUSM-TMP1-A-1-0-D-A83B-36) from MP2PRT case MP2PRT-PAPUSM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.4 years (2,345 days).
Specimen MP2PRT-PAPUSM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 718566f3-52de-4918-b21c-8971d4bcf844.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPUSM-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPUSM-NM1-A-1-0-D-A83B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/30d798b2-ced2-4e08-939f-c4d1555b0f03

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 3, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CC2D2B | c.193C>T p.R65* | Nonsense Mutation (SNP) | VAF 74/341 reads (22%) | catalogued as rs1215015186, COSV100729452; called by muse, mutect2, varscan2
- CCDC141 | c.4196G>A p.S1399N | Missense Mutation (SNP) | VAF 58/217 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756977503; called by muse, mutect2, varscan2
- ECEL1 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 20/656 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV58813640; called by muse, mutect2
- FLT3 | c.1727T>C p.L576P | Missense Mutation (SNP) | VAF 9/249 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV54047457, COSV54049031, COSV54049919; called by muse, mutect2
- KLB | c.74G>A p.R25H | Missense Mutation (SNP) | VAF 63/300 reads (21%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs755268107; called by muse, mutect2, varscan2
- MUC3A | c.443C>T p.T148M | Missense Mutation (SNP) | VAF 24/453 reads (5%) | SIFT tolerated, low confidence (0.17); catalogued as rs781659697, COSV60212876; called by muse, mutect2
- PDLIM4 | c.538C>T p.R180W | Missense Mutation (SNP) | VAF 134/400 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.781); catalogued as rs747690565; called by muse, mutect2, varscan2
- PNLIP | c.421G>A p.V141M | Missense Mutation (SNP) | VAF 63/326 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs775944341, COSV65040417; called by muse, mutect2, varscan2
- RBMXL3 | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 112/332 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.527); catalogued as rs782285858; called by muse, mutect2, varscan2
- RNF150 | c.997G>A p.D333N | Missense Mutation (SNP) | VAF 34/230 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.261); catalogued as rs138178278; called by muse, mutect2, varscan2
- SPEF2 | c.2899G>A p.A967T | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs773002918, COSV61548840, COSV61549825; called by muse, mutect2
- ADAMTSL2 | c.2494C>T p.R832C | Missense Mutation (SNP) | VAF 55/686 reads (8%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.862); called by muse, mutect2
- GUCY1A2 | c.586T>G p.L196V | Missense Mutation (SNP) | VAF 73/429 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MROH9 | c.1958T>A p.V653D | Missense Mutation (SNP) | VAF 62/307 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- RPS13 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 24/364 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.554); called by muse, mutect2
- IHH | c.1050C>T p.A350= | Silent (SNP) | VAF 34/452 reads (8%) | catalogued as rs747612055, COSV55393166; called by muse, mutect2
- PCSK5 | c.867G>A p.R289= | Silent (SNP) | VAF 30/354 reads (8%) | catalogued as COSV65096589; called by muse, mutect2
- ZKSCAN8 | c.219G>A p.R73= | Silent (SNP) | VAF 95/386 reads (25%) | called by muse, mutect2, varscan2
- TRGJP | chr7:38276318 ins ATGCC | 5'Flank (INS) | VAF 41/169 reads (24%) | called by mutect2, pindel, varscan2
